Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8338, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8338-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

█ y/o male with large left renal mass found incidentally. Left radical nephrectomy today.

Specimens Submitted:

1: SP: kidney, left, radical nephrectomy █

2: SP: lymph nodes, left periaortic, excision █

3: SP: lymph nodes, left hilar, excision █

DIAGNOSIS:

1. SP: kidney, left, radical nephrectomy █

Tumor Type:

Renal cell carcinoma - Chromophobe type

Tumor Size:

Greatest diameter is 12.5 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Not identified

Vessels with muscular wall are involved by tumor in the renal sinus

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

2. SP: lymph nodes, left periaortic, excision █

Lymph Nodes:

Number of nodes examined:5

Number of metastatic nodes:0

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

3. SP: lymph nodes, left hilar, excision

Lymph Nodes:

Number of nodes examined:1

Number of metastatic nodes:0

Unremarkable ectopic adrenal tissue

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh labeled "left kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 1100 g in total. The kidney measures 15.0 x 11.0 x 7.0 cm. The attached ureter measures 7.0 cm in length and 0.2 cm in diameter. The attached renal vein measures 1.0 cm in length and 0.5 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a 12.5 x 10.0 x 7.0 cm cortical mass located in the mid portion of the kidney. The cut surface of the mass is tan, hemorrhagic and necrotic. The mass invades the Gerota's fascia grossly but does not invade the renal pelvis. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined corticomedullary junction. The cortex measures 0.5 cm and the calyces appear normal. No lymph nodes identified. Representative sections are submitted for TPS and for permanent sections. Photograph has been taken.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

U -- ureter representative sections

K -- representative sections of kidney

TG --tumor with capsule

2). The specimen is received in formalin, labeled "left periaortic lymph node" and consists of multiple pink tan firm lymph nodes ranging from 0.5 to 2.0 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

3). The specimen is received in formalin, labeled "left hilar lymph node" and consists of 1.0 x 1.0 x 0.5 cm portion of adipose tissue. No lymph node identified. Entirely submitted.

Summary of sections:

U- undesignated

Summary of Sections:

Part 1: SP: kidney, left, radical nephrectomy

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Block	Sect. Site	PCs
2	k	2
7	t	7
4	tg	4
1	thf	1
2	tk	2
2	tsf	2
1	u	1
1	uvm	1

Part 2: SP: lymph nodes, left periaortic, excision

Block	Sect. Site	PCs
3	ln	3

Part 3: SP: lymph nodes, left hilar, excision

Block	Sect. Site	PCs
1	u	1

Source: NCI Genomic Data Commons file 8b1f0c8e-7621-4054-b21b-d29be5a6e55d (TCGA-KL-8338.C7322E2D-4068-49AA-B8E0-D4FD1B2CDBA0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).